FM case AD27 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/cc46205c-73d2-4f98-89bb-79bb5664d0cf

Female, 55.2 years: Infiltrating duct carcinoma, NOS (ICD-O-3 8500/3) of the breast. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
